Gene-level copy-number profile of tumor specimen TCGA-HT-A5R7-01A from TCGA case TCGA-HT-A5R7, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 33.1 years (12,092 days).
Specimen TCGA-HT-A5R7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.16595244-75db-458e-9e66-b49083522159.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-A5R7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/52a46b72-3b5a-427b-b846-2cd56db25041

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,493; copy number 2: 56,912; copy number 3: 188; copy number 4: 79; copy number 6: 19; copy number 7: 1; copy number 9: 3; copy number 10: 21; copy number 12: 31; copy number 14: 23; copy number 19: 17; copy number 30: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-A5R7-01A-11D-A288-01): tumor purity 0.9, ploidy 3.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 148 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–56,524,959, 97 genes, copy number 6–19 (broad region; genes not listed).
- chr4:56,907,876–56,977,606, 3 genes, copy number 9: REST, AC069307.1, NOA1.
- chr7:86,876,906–87,059,654, 1 gene, copy number 7 (within-gene range 3–7): ELAPOR2.
- chr7:91,940,862–93,574,730, 33 genes, copy number 30: AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489.
- chr7:116,672,196–116,954,334, 8 genes, copy number 6 (within-gene range 2–6): MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7.
- chr7:116,954,480–116,972,911, 6 genes, copy number 6: AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1.

Autosomal genes at a single copy (total copy number 1): 2,493. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
